Gene-level copy-number profile of tumor specimen TCGA-CG-5730-01A from TCGA case TCGA-CG-5730, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 80.6 years (29,432 days).
Specimen TCGA-CG-5730-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.1d857518-eff7-4ecf-b452-0be346708268.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CG-5730-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3a271d4e-9485-44cc-8385-1a771bb6122e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 12,978; copy number 3: 29,914; copy number 4: 14,044; copy number 5: 1,530; copy number 6: 533; copy number 7: 152; copy number 9: 96; copy number 10: 308; copy number 14: 93; copy number 16: 45; copy number 17: 32; copy number 20: 11; copy number 25: 70; copy number 35: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CG-5730-01A-11D-1599-01): tumor purity 0.74, ploidy 3.12, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 811 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,381,392–43,687,791, 96 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr17:34,479,272–36,177,510, 91 genes, copy number 7–35 (broad region; genes not listed).
- chr17:39,603,536–42,155,044, 168 genes, copy number 7–25 (within-gene range 3–25) (broad region; genes not listed).
- chr17:57,955,965–69,327,244, 363 genes, copy number 7–17 (within-gene range 2–17) (broad region; genes not listed).
- chr17:73,334,384–75,757,818, 93 genes, copy number 14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
